CPTAC case C3L-01288 — Kidney — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/83cb7840-8d02-408d-a7c2-b446f991cfa3

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1946; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Renal cell carcinoma, NOS: ICD-O-3 morphology code: 8312/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 70.9 years (25,898 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T1a; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G1; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 1,800 days (4.9 years); Progression or recurrence: yes; Days to recurrence: 1,416 days (3.9 years); Days to last follow up: 1,800 days (4.9 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.8 cm (a second GDC size field records 6.5 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Margin status: Uninvolved; Sarcomatoid present: No.

Follow-up (6 entries)
- Days to follow up: 358 days; Disease response: Tumor Free.
- Days to follow up: 703 days (1.9 years); Disease response: Tumor Free.
- Days to follow up: 1,066 days (2.9 years); Disease response: Tumor Free.
- Days to follow up: 1,435 days (3.9 years); Disease response: With Tumor.
- Days to follow up: 1,435 days (3.9 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 1,416 days (3.9 years).
- Days to follow up: 1,800 days (4.9 years); Disease response: With Tumor.

Other clinical attributes
- Weight: 101 kg; Height: 160 cm; BMI: 39.45.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 52; Cigarettes per day: 20; Tobacco smoking onset year: 1964; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 58.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-01288-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 211 mg; Time between clamping and freezing: 27 minutes; Time between excision and freezing: 16 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-01288-22: Section location: Middle; Percent tumor nuclei: 90; Percent necrosis: 2.
- Sample C3L-01288-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 0.209 mg.
- Sample C3L-01288-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
